Gene-level copy-number profile of tumor specimen C3N-03665-01 from CPTAC case C3N-03665, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.4 years (23,168 days).
Specimen C3N-03665-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8964924f-6e62-4d39-a5c7-d59cfd6230dc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03665-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/15c20a5b-e2e1-4610-9cc5-ffb4f60af5d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 516; copy number 1: 8,079; copy number 2: 41,933; copy number 3: 6,875; copy number 4: 541; copy number 5: 840; copy number 6: 120; copy number 7: 5.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–149,556,361, 4 genes: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 965 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:37,154,761–42,051,784, 147 genes, copy number 5 (broad region; genes not listed).
- chr1:149,606,334–149,747,818, 6 genes, copy number 6–7 (within-gene range 2–7): LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3.
- chr1:149,754,301–162,868,815, 644 genes, copy number 5–6 (broad region; genes not listed).
- chr9:33,461,353–36,677,683, 153 genes, copy number 5 (broad region; genes not listed).
- chr18:29,048,620–31,359,246, 14 genes, copy number 5 (within-gene range 1–5): RNU6-408P, AC105245.1, AC074237.1, AC117569.1, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1, DSG1.
- chr18:31,345,362–31,345,467, 1 gene, copy number 5 (within-gene range 1–5): RNU6-167P.

Autosomal genes at a single copy (total copy number 1): 5,735. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
